Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A8O7, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A8O7-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor occupies bladder wall. It is invasive and protruded, ill - margins with 4x3x2.5cm in size, soft and gray surface.

Microscopic Description: Tumor cells are hyperplastic to arrange to form papillary or trabeculae or cords one by one. Tumor cells have moderate and eosinophilic. Nuclei are very enlarged and variability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in muscle propria

Diagnosis Details: Infiltrating urothelial carcinoma, low-grade, infiltrating in muscle propria

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 4 x 3 x 2.5 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Muscularis propria

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Not specified

Comments: None

ICD-6 3
C64.0
Carcinoma, urothelial NOS
8124/3
path
Carcinoma, transitional cell NOS
8120/3
Site: 4 Bladder NOS
C67.9
JW 11/26/13

Source: NCI Genomic Data Commons file 2c60bb9a-7cf5-4944-907d-1ba7bb727be8 (TCGA-E7-A8O7.6EF2834F-F28C-4E95-AC82-568590C9444D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).